Gene-level copy-number profile of tumor specimen TCGA-10-0927-01A from TCGA case TCGA-10-0927, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 65.7 years (23,982 days).
Specimen TCGA-10-0927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0afd6963-4ee0-474d-89b9-4fa151d8f1b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-10-0927-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc89953c-d46e-4ee2-8e5e-3a5937662e30

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,818; copy number 2: 20,697; copy number 3: 22,401; copy number 4: 9,615; copy number 5: 1,714; copy number 6: 1,038; copy number 7: 5; copy number 8: 126; copy number 9: 7; copy number 10: 112; copy number 14: 168; copy number 16: 119.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-10-0927-01A-02D-0399-01): tumor purity 0.82, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 537 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:58,872,149–59,130,875, 5 genes, copy number 7: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1.
- chr18:20,946,906–42,115,538, 293 genes, copy number 9–16 (broad region; genes not listed).
- chr18:42,270,589–42,270,715, 1 gene, copy number 9: RNA5SP454.
- chr19:12,833,951–15,126,174, 112 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).
- chr19:38,108,500–40,348,527, 126 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
